Somatic mutation profile of tumor specimen TCGA-CG-5727-01A (aliquot TCGA-CG-5727-01A-11D-1600-08) from TCGA case TCGA-CG-5727, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 66.5 years (24,289 days).
Specimen TCGA-CG-5727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 422dcf8e-7a20-4dcb-b722-f13de4d667a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5727-11A (Solid Tissue Normal), aliquot TCGA-CG-5727-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efd8b69c-3c43-4fbd-91b2-08f8b32c32e7

The open-access MAF lists 172 somatic variants for this specimen: 117 protein-altering or splice-affecting, 50 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 50, Nonsense Mutation 5, Intron 4, Splice Region 3, Nonstop Mutation 2, Splice Site 1, RNA 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/75 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs557707047, COSV57051383; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB1 | c.2044C>T p.L682F | Missense Mutation (SNP) | VAF 264/445 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as rs1323794979, COSV55947866; called by muse, mutect2, varscan2
- ABCB4 | c.1006G>T p.V336F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs551592504, COSV55933640; called by muse, varscan2
- ABCC8 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs776764243, COSV56847968; called by muse, mutect2, varscan2
- ADAR | c.1846G>A p.V616I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.993); catalogued as rs570647049, COSV52713382; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- ADCK1 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs140603078; called by muse, mutect2, varscan2
- AGBL2 | c.2663C>T p.A888V | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1446582774, COSV54090945; called by muse, mutect2, varscan2
- ALS2 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1008414779, COSV51885479; called by muse, mutect2, varscan2
- ALS2CL | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59670800; called by muse, mutect2, varscan2
- ATP11C | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV59561030; called by muse, mutect2, varscan2
- BARHL2 | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs764642090, COSV64981012, COSV64981943; called by muse, mutect2, varscan2
- BCAS3 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.931); catalogued as COSV66771477; called by muse, mutect2, varscan2
- BEND5 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV65716263; called by muse, mutect2, varscan2
- BICC1 | c.1233G>T p.R411S | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV54062733, COSV54065128; called by muse, mutect2, varscan2
- BICD1 | c.629C>A p.T210K | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.574); catalogued as rs367637446, COSV55676834; called by muse, mutect2, varscan2
- C11orf87 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV59356192; called by muse, mutect2, varscan2
- C3 | c.4400T>A p.F1467Y | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV55570783; called by muse, mutect2, varscan2
- CES5A | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs377067784, COSV51865112; called by muse, mutect2, varscan2
- CLDN25 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as rs764892613, COSV71620422; called by muse, mutect2, varscan2
- COL11A1 | c.3701G>A p.G1234E | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62177466; called by muse, mutect2, varscan2
- COL12A1 | c.9103C>T p.R3035* | Nonsense Mutation (SNP) | VAF 73/157 reads (46%) | catalogued as rs1352539003, COSV59392382; called by muse, mutect2, varscan2
- CPNE9 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV56004073; called by muse, mutect2
- CSF2RB | c.1394T>C p.I465T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV99453645; called by muse, mutect2
- CSMD3 | c.6082A>C p.N2028H (on ENST00000297405 / NM_001363185.1; = p.N1924H on NM_052900.3) | Missense Mutation (SNP) | VAF 57/356 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.106); catalogued as COSV52136701; called by muse, mutect2, varscan2
- CYB5R4 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV63750477; called by muse, mutect2, varscan2
- DBX1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as COSV57053759; called by muse, mutect2, varscan2
- DHX30 | c.1795T>A p.F599I (on ENST00000445061 / NM_138615.3; = p.F560I on NM_014966.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.247); catalogued as COSV53136420; called by muse, mutect2, varscan2
- DLG2 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771409477, COSV54631541; called by muse, mutect2, varscan2
- DNAH7 | c.977C>G p.T326S | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as COSV56757480; called by muse, mutect2, varscan2
- DPY19L3 | c.748T>A p.S250T | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.049); catalogued as COSV100639160; called by muse, mutect2
- DST | c.11480A>G p.N3827S (on ENST00000361203 / NM_001374722.1; = p.N1415S on NM_015548.5) | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs1277492242, COSV55005146; called by muse, mutect2, varscan2
- DYNLRB1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs199786050, COSV55963820; called by muse, mutect2, varscan2
- DYSF | c.1929C>T p.D643= | Splice Region (SNP) | VAF 25/108 reads (23%) | catalogued as rs574076669, COSV50282226, COSV50642791; called by muse, mutect2, varscan2
- EIF4A2 | c.836T>C p.F279S | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV56216296; called by muse, mutect2, varscan2
- EP400 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs779183271, COSV57767928; called by muse, mutect2, varscan2
- EPHA5 | c.183G>T p.V61= | Splice Region (SNP) | VAF 22/108 reads (20%) | catalogued as COSV56637390; called by muse, mutect2, varscan2
- FAT2 | c.11749G>A p.V3917M | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as rs756607776, COSV55816219; called by muse, mutect2, varscan2
- FAT4 | c.10045C>A p.Q3349K | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.295); catalogued as COSV58677319; called by muse, mutect2, varscan2
- FGF1 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1004435823, COSV61803509; called by muse, mutect2, varscan2
- FLG | c.11483C>T p.S3828L | Missense Mutation (SNP) | VAF 205/586 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs774898663, COSV64238987; called by muse, varscan2
- GAS2L3 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57156586, COSV57159424; called by muse, mutect2, varscan2
- GFI1 | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs777241871, COSV54041845; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLRB | c.726C>A p.N242K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.187); catalogued as COSV52414863; called by muse, mutect2
- H2AC21 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58611664; called by muse, mutect2, varscan2
- HERC4 | c.2449C>T p.P817S (on ENST00000395198 / NM_022079.3; = p.P809S on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53269543; called by muse, mutect2, varscan2
- IGF2R | c.7405C>T p.Q2469* | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as COSV63627731; called by muse, mutect2, varscan2
- IGKV1D-8 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs550214215; called by muse, mutect2, varscan2
- IL36RN | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV61010421; called by muse, mutect2, varscan2
- KCND2 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 51/161 reads (32%) | catalogued as rs1272576215, COSV58574029, COSV58575568; called by muse, mutect2, varscan2
- KRT2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 77/256 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs547255945, COSV59009678; called by muse, varscan2
- KRT84 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 120/345 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs146876431; called by muse, varscan2
- KRTAP13-1 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs763603199, COSV100819897, COSV62663095; called by muse, mutect2, varscan2
- LAMC3 | c.4447G>A p.E1483K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367784109; called by muse, mutect2, varscan2
- LRP12 | c.1110A>C p.Q370H | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.979); catalogued as COSV52626232; called by muse, mutect2, varscan2
- NARS1 | c.1590G>T p.R530S | Missense Mutation (SNP) | VAF 46/252 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV56876225; called by muse, mutect2, varscan2
- NAV3 | c.6755G>A p.G2252D (on ENST00000397909 / NM_001024383.2; = p.G2230D on NM_014903.6) | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV57070058; called by muse, mutect2, varscan2
- NCOA7 | c.2734G>A p.G912R | Missense Mutation (SNP) | VAF 38/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57652025, COSV57660962; called by muse, mutect2, varscan2
- NOTCH2 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs782452794, COSV56686773; called by muse, mutect2, varscan2
- NPFF | c.340T>A p.*114Rext*5 | Nonstop Mutation (SNP) | VAF 64/217 reads (29%) | catalogued as COSV57199278; called by muse, mutect2, varscan2
- OR10H5 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.089); catalogued as rs776618344, COSV58277743, COSV58277919; called by muse, mutect2, varscan2
- OR4C15 | c.1112A>T p.*371Lext*? (on ENST00000314644; = p.*317Lext*? on NM_001001920.2) | Nonstop Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100115572; called by mutect2, varscan2
- OR5T1 | c.304A>G p.K102E | Missense Mutation (SNP) | VAF 127/331 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as COSV57302094; called by muse, mutect2, varscan2
- PCDH15 | c.3394A>G p.I1132V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV57281346; called by muse, mutect2, varscan2
- PCDHA9 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); catalogued as rs762397793, COSV65324104, COSV65324744; called by muse, mutect2, varscan2
- PERP | c.363C>G p.F121L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.113); catalogued as COSV69827420; called by muse, mutect2, varscan2
- PLEKHH3 | c.2269A>T p.S757C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV52217167; called by muse, mutect2, varscan2
- PPP2R1A | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs148604195, COSV59043195; called by muse, mutect2
- PRKG1 | c.936G>T p.G312= | Splice Region (SNP) | VAF 35/90 reads (39%) | catalogued as COSV64768157; called by muse, mutect2, varscan2
- PRMT2 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52454682; called by muse, mutect2, varscan2
- PRRX2 | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV65241890; called by muse, mutect2, varscan2
- PTPRJ | c.3374G>A p.R1125H | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs374260795, COSV101394690; called by muse, mutect2
- PTPRN | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55346703; called by muse, mutect2
- PVALB | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 55/275 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV53412088; called by muse, mutect2, varscan2
- RASSF2 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0.009); catalogued as COSV65081924; called by muse, mutect2, varscan2
- RBCK1 | c.1386G>C p.W462C (on ENST00000356286 / NM_031229.4; = p.W420C on NM_006462.6) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1390985798, COSV62291967; called by muse, mutect2
- SCN2A | c.2211G>C p.L737F | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780959122, COSV51836437; called by muse, mutect2, varscan2
- SCNN1D | c.509G>T p.G170V (on ENST00000338555; = p.G334V on NM_001130413.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.105); catalogued as COSV57640731; called by muse, mutect2, varscan2
- SDHA | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as rs375396913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEPTIN4 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1326720798, COSV57894012; called by muse, mutect2, varscan2
- SIPA1L3 | c.1154C>T p.T385M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as rs141710131; called by muse, mutect2, varscan2
- SLC2A3 | c.1021G>T p.G341W | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50001434; called by muse, mutect2, varscan2
- SLC39A12 | c.497A>G p.D166G | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs781790857, COSV66196660; called by muse, mutect2, varscan2
- SLC43A2 | c.1613A>G p.Y538C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV56768441; called by muse, mutect2, varscan2
- SLITRK6 | c.1407C>A p.N469K | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68389566; called by muse, mutect2, varscan2
- SMO | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 313/505 reads (62%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.976); catalogued as rs1213477185, COSV50825739; called by muse, mutect2, varscan2
- SNX9 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.818); catalogued as COSV67583603; called by muse, mutect2, varscan2
- SON | c.2912G>A p.R971K | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV51654086; called by muse, mutect2, varscan2
- SPG7 | c.2165C>T p.A722V (on ENST00000268704; = p.A729V on NM_003119.4) | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51948912; called by muse, mutect2
- SPTLC3 | c.1114A>C p.S372R | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100982890, COSV65464481; called by muse, mutect2, varscan2
- SS18 | c.986A>C p.Y329S (on ENST00000415083 / NM_001007559.3; = p.Y298S on NM_005637.3) | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.987); catalogued as COSV52260181; called by muse, mutect2, varscan2
- ST8SIA2 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 81/223 reads (36%) | PolyPhen benign (0.077); catalogued as rs752330245, COSV51568153; called by muse, mutect2, varscan2
- STARD8 | c.1993C>A p.L665I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV52923566; called by muse, mutect2
- SUGP1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs150375001, COSV55920804; called by muse, mutect2, varscan2
- SULF1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV52677297, COSV99482980; called by muse, mutect2, varscan2
- TAS2R13 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs754206581, COSV66831542; called by muse, mutect2, varscan2
- TCF7 | c.1026+1G>A p.X342_splice | Splice Site (SNP) | VAF 4/11 reads (36%) | catalogued as rs777726841, COSV58656055; called by muse, mutect2, varscan2
- TSHZ3 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs778937078, COSV53667493; called by muse, mutect2, varscan2
- TTK | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV57882599; called by muse, mutect2, varscan2
- TTN | c.24679G>C p.G8227R (on ENST00000591111; = p.G7300R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | PolyPhen possibly damaging (0.676); catalogued as COSV59958866; called by muse, mutect2, varscan2
- UGDH | c.1364T>C p.I455T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs755764491, COSV57097186; called by muse, mutect2, varscan2
- UGT2B17 | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs148107155; called by muse, mutect2, varscan2
- UNC13A | c.4030G>A p.A1344T | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as rs759586125, COSV53191477; called by muse, mutect2, varscan2
- VASN | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs756788083, COSV52028893; called by muse, mutect2, varscan2
- ZBTB21 | c.623G>T p.W208L | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV60403592; called by muse, mutect2, varscan2
- ZEB1 | c.2652G>C p.Q884H | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV58040212, COSV58040315; called by muse, mutect2
- ZEB2 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs730881194, COSV100356718, COSV57953987; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZNF264 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV54041199; called by muse, mutect2, varscan2
- ZNF331 | c.1181A>G p.Y394C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.907); catalogued as COSV53475763; called by muse, mutect2, varscan2
- ZNF578 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs750649417, COSV69736036; called by muse, varscan2
- ZNF71 | c.1095G>C p.K365N | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.684); catalogued as rs1386285784, COSV60147143; called by muse, mutect2, varscan2
- ZNF746 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 205/269 reads (76%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs766494668, COSV61406835; called by muse, mutect2, varscan2
- SOX9 | c.514dup p.Y172Lfs*80 | Frame Shift Ins (INS) | VAF 8/55 reads (15%) | called by mutect2, pindel, varscan2
- TRIM75P | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF701 | c.1257del p.Y420Tfs*21 (on ENST00000301093; = p.Y354Tfs*21 on NM_018260.3) | Frame Shift Del (DEL) | VAF 27/206 reads (13%) | called by mutect2, varscan2
- ABCC8 | c.1828C>T p.L610= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV56847961; called by muse, mutect2, varscan2
- ACTN3 | c.2646G>A p.P882= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs768201265, COSV59748028; called by muse, mutect2, varscan2
- AHNAK2 | c.6186C>T p.P2062= | Silent (SNP) | VAF 64/144 reads (44%) | catalogued as rs547642658, COSV60911387; called by muse, mutect2, varscan2
- ANKRD49 | c.321T>C p.D107= | Silent (SNP) | VAF 19/126 reads (15%) | catalogued as COSV57059926; called by muse, mutect2, varscan2
- ANO3 | c.672G>A p.L224= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV56785563; called by muse, mutect2, varscan2
- ANXA4 | c.84C>T p.A28= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV67848585; called by muse, mutect2, varscan2
- ARID4B | c.2559C>T p.C853= | Silent (SNP) | VAF 57/318 reads (18%) | catalogued as COSV51600833; called by muse, mutect2, varscan2
- BEND5 | c.849C>T p.P283= | Silent (SNP) | VAF 49/280 reads (18%) | catalogued as rs146041042, COSV65716780; called by muse, mutect2, varscan2
- BRPF1 | c.3486G>C p.L1162= | Silent (SNP) | VAF 68/296 reads (23%) | catalogued as COSV57351941; called by muse, varscan2
- CBARP | c.156C>A p.G52= (on ENST00000382477; = p.G58= on NM_152769.3) | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV53068252; called by muse, mutect2, varscan2
- CDC7 | c.387T>C p.H129= | Silent (SNP) | VAF 68/307 reads (22%) | catalogued as COSV52310014; called by muse, mutect2, varscan2
- CFAP161 | c.885C>A p.A295= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as COSV54428740; called by muse, mutect2, varscan2
- CHSY1 | c.2184C>A p.V728= | Silent (SNP) | VAF 74/226 reads (33%) | catalogued as COSV54252053; called by muse, mutect2, varscan2
- CSH2 | c.468C>T p.D156= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as rs761766182, COSV61081250; called by muse, mutect2, varscan2
- DLG3 | c.1935C>A p.I645= (on ENST00000374360 / NM_021120.4; = p.I340= on NM_020730.3) | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as rs1355257535, COSV52080815, COSV99529657; called by muse, mutect2, varscan2
- DNAH11 | c.630T>G p.T210= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV60947743; called by muse, mutect2, varscan2
- DPY19L3 | c.747A>T p.I249= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV100639159; called by muse, mutect2
- DYSF | c.3630C>T p.I1210= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV50282359, COSV50291840; called by muse, mutect2, varscan2
- ERF | c.912C>T p.S304= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs1453343192, COSV55895347; called by muse, mutect2
- FAT4 | c.13380G>A p.T4460= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs146914959; called by muse, mutect2, varscan2
- FKBP10 | c.897C>T p.D299= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs560280765, COSV58636152; called by muse, mutect2, varscan2
- GFPT2 | c.198C>T p.L66= | Silent (SNP) | VAF 138/412 reads (33%) | catalogued as rs749603564, COSV53807384; called by muse, mutect2, varscan2
- ITGA5 | c.3102C>T p.T1034= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs745882584, COSV53216464; called by muse, mutect2, varscan2
- LDB1 | c.753C>T p.P251= (on ENST00000425280 / NM_001321612.2; = p.P215= on NM_003893.5) | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2
- MYH15 | c.1260C>T p.N420= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as rs774875091, COSV56305700; called by muse, mutect2, varscan2
- NOX5 | c.1752C>T p.A584= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as rs774041090, COSV52986729; called by muse, mutect2, varscan2
- ODAPH | c.87G>A p.T29= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as rs779985232, COSV61141208; called by mutect2, varscan2
- OR8J3 | c.207C>A p.I69= | Silent (SNP) | VAF 77/219 reads (35%) | catalogued as COSV56879840; called by muse, mutect2, varscan2
- PAPPA | c.3558C>T p.P1186= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as rs182838434; called by muse, mutect2, varscan2
- PCDHA12 | c.1776G>A p.A592= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV56488016; called by muse, mutect2, varscan2
- PCDHB13 | c.1620G>A p.A540= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV53394590, COSV53399179; called by muse, mutect2, varscan2
- RASAL2 | c.2160G>A p.V720= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as COSV62711636; called by muse, mutect2, varscan2
- RBM47 | c.942G>A p.T314= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1336723731, COSV55932286; called by muse, mutect2, varscan2
- RSPH10B2 | c.2517C>T p.D839= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs1417586037; called by mutect2, varscan2
- RYR1 | c.5061C>T p.H1687= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs1287517085, COSV62091083; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN2A | c.3435G>A p.T1145= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs1345931602, COSV51836457; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMG1 | c.723G>A p.A241= | Silent (SNP) | VAF 38/396 reads (10%) | catalogued as rs201859336; called by muse, mutect2
- SERPINA3 | c.954C>T p.I318= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as COSV67585586; called by muse, mutect2, varscan2
- SLC16A7 | c.87C>A p.S29= | Silent (SNP) | VAF 11/137 reads (8%) | called by muse, mutect2
- SLIT3 | c.2232C>T p.R744= | Silent (SNP) | VAF 37/169 reads (22%) | catalogued as rs779092935, COSV60600964; called by muse, mutect2, varscan2
- SLITRK5 | c.1263C>T p.I421= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV61520598; called by muse, mutect2, varscan2
- SVEP1 | c.2685C>T p.I895= | Silent (SNP) | VAF 138/321 reads (43%) | catalogued as rs1376161503, COSV57032759; called by muse, mutect2, varscan2
- TECPR2 | c.3486G>A p.T1162= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs747983532, COSV63969657; ClinVar: likely benign; called by muse, mutect2, varscan2
- TG | c.7137C>T p.R2379= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs748875849, COSV99599191; called by muse, varscan2
- TPTE | c.756A>G p.P252= (on ENST00000618007 / NM_199261.4; = p.P234= on NM_199259.4) | Silent (SNP) | VAF 34/580 reads (6%) | catalogued as rs1039080151; called by muse, mutect2
- TRIM50 | c.420C>A p.I140= | Silent (SNP) | VAF 36/236 reads (15%) | catalogued as COSV60792107; called by muse, mutect2, varscan2
- TSGA10 | c.1803G>A p.L601= | Silent (SNP) | VAF 41/154 reads (27%) | catalogued as COSV61822621, COSV61823164; called by muse, mutect2, varscan2
- VWF | c.6555G>T p.R2185= | Silent (SNP) | VAF 37/136 reads (27%) | catalogued as COSV54615404; called by muse, mutect2, varscan2
- YTHDC2 | c.762C>T p.I254= | Silent (SNP) | VAF 41/215 reads (19%) | catalogued as rs199867041; called by muse, mutect2, varscan2
- ZBBX | c.2223A>C p.T741= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as rs1326724347, COSV56785671; called by muse, mutect2, varscan2
- MIR412 | n.85G>A | RNA (SNP) | VAF 27/127 reads (21%) | catalogued as rs373476147; called by muse, mutect2, varscan2
- PCDHGA4 | c.2514+26A>G | Intron (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- PSG5 | c.431-2990C>A | Intron (SNP) | VAF 57/308 reads (19%) | catalogued as COSV100742679; called by muse, mutect2, varscan2
- PSG5 | c.431-2991C>A | Intron (SNP) | VAF 54/306 reads (18%) | catalogued as COSV100742681; called by muse, mutect2, varscan2
- TCF3 | c.1823-514G>A | Intron (SNP) | VAF 18/107 reads (17%) | catalogued as rs759178145, COSV99513875; called by muse, mutect2, varscan2
